Somatic mutation profile of tumor specimen TCGA-FW-A5DX-01A (aliquot TCGA-FW-A5DX-01A-11D-A27K-08) from TCGA case TCGA-FW-A5DX, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.4 years (26,067 days).
Specimen TCGA-FW-A5DX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d2b3440-a704-4250-9914-ed9522af9000.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FW-A5DX-10A (Blood Derived Normal), aliquot TCGA-FW-A5DX-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fcf245d-d774-4854-baf8-cba8066023e5

The open-access MAF lists 232 somatic variants for this specimen: 150 protein-altering or splice-affecting, 75 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 75, Nonsense Mutation 11, RNA 4, Frame Shift Del 2, Intron 2, Splice Region 1, Splice Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACSL5 | c.158G>A p.G53E (on ENST00000354273; = p.G109E on NM_016234.3) | Missense Mutation (SNP) | VAF 50/55 reads (91%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV61131276; called by muse, mutect2, varscan2
- AHNAK2 | c.5224C>T p.P1742S | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1470449082, COSV60907092; called by muse, mutect2, varscan2
- AKNA | c.2821C>A p.P941T | Missense Mutation (SNP) | VAF 150/162 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56313151; called by muse, mutect2, varscan2
- AMY1B | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100375560; called by mutect2, varscan2
- ANGEL1 | c.1340G>A p.R447K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV51873800, COSV99200360; called by muse, varscan2
- ANLN | c.2381A>G p.Q794R | Missense Mutation (SNP) | VAF 126/221 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV56076982; called by muse, mutect2, varscan2
- AP2A1 | c.1445C>T p.T482I | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs576480748, COSV62819049; called by muse, mutect2, varscan2
- ATP1A4 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV63626824; called by muse, mutect2, varscan2
- ATP8B4 | c.1126A>T p.T376S | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.942); catalogued as COSV52717260; called by muse, mutect2, varscan2
- B3GNT8 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs199940501, COSV54197700; called by muse, mutect2, varscan2
- BCL11A | c.2227T>C p.Y743H (on ENST00000335712 / NM_001365609.1; = p.Y777H on NM_022893.4) | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100186700, COSV59631451; called by muse, mutect2, varscan2
- BMPER | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 170/308 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as COSV51821322; called by muse, mutect2, varscan2
- BRINP3 | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 155/193 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs573063381, COSV66527285; called by muse, mutect2, varscan2
- C10orf71 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV60508727; called by muse, mutect2, varscan2
- CACNA2D3 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.903); catalogued as rs753921913, COSV55513596; called by muse, mutect2, varscan2
- CAMTA1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.788); catalogued as COSV57905691; called by muse, mutect2
- CCER1 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs866835578, COSV62646213, COSV62647243; called by muse, mutect2, varscan2
- CDH23 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99820633; called by muse, mutect2, varscan2
- CDH23 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.955); catalogued as COSV99820639; called by muse, mutect2, varscan2
- CEP128 | c.2194C>T p.H732Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs527705008, COSV55379545; called by muse, mutect2, varscan2
- CEP20 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99739812; called by muse, mutect2, varscan2
- CFHR2 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100804315; called by muse, mutect2, varscan2
- CHD6 | c.4148C>A p.P1383Q | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV64691585; called by muse, mutect2, varscan2
- CHD7 | c.6923C>T p.S2308L | Missense Mutation (SNP) | VAF 108/112 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs768152792, COSV71111625; called by muse, mutect2, varscan2
- CHL1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV56595589; called by muse, mutect2
- CLVS1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 110/115 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs143211270, COSV57975512, COSV99073593; called by muse, mutect2, varscan2
- COL28A1 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68082625; called by muse, mutect2, varscan2
- COL4A6 | c.1351C>A p.H451N | Missense Mutation (SNP) | VAF 79/82 reads (96%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57868695, COSV57872884; called by muse, mutect2, varscan2
- CPA4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 116/236 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55983603, COSV55984811; called by muse, mutect2, varscan2
- CYC1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 315/453 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100010366; called by muse, mutect2, varscan2
- DNAH3 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs777984798, COSV54506633; called by muse, mutect2, varscan2
- DNAH3 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 49/53 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV54527539; called by muse, mutect2, varscan2
- DPY19L3 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV60477475; called by muse, mutect2, varscan2
- ELP2 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 78/126 reads (62%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV60851597; called by muse, mutect2, varscan2
- EPAS1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 104/107 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750239808, COSV55387318; called by muse, mutect2, varscan2
- ERICH1 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 145/186 reads (78%) | catalogued as COSV50638602; called by muse, mutect2, varscan2
- ESRP1 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 159/235 reads (68%) | catalogued as rs1236801174, COSV64410337; called by muse, mutect2, varscan2
- EVC2 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 239/326 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs377461598, COSV60395332; called by muse, mutect2, varscan2
- FABP6 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV67437147; called by muse, mutect2, varscan2
- FBXW8 | c.187C>T p.P63S (on ENST00000309909; = p.P101S on NM_012174.1) | Missense Mutation (SNP) | VAF 48/50 reads (96%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV59300028; called by muse, mutect2, varscan2
- FHOD3 | c.2933C>T p.P978L (on ENST00000359247 / NM_001281739.3; = p.P995L on NM_025135.5) | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57165760, COSV57175798; called by muse, mutect2
- FLI1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61381275, COSV61382396; called by muse, mutect2, varscan2
- FOXRED2 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV53400288; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1838C>T p.S613F | Missense Mutation (SNP) | VAF 73/89 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557525685, COSV58556577; called by muse, mutect2, varscan2
- FSIP2 | c.20517G>A p.K6839= | Splice Region (SNP) | VAF 46/52 reads (88%) | catalogued as COSV100554976; called by muse, mutect2, varscan2
- FSIP2 | c.20517+1G>T p.X6839_splice | Splice Site (SNP) | VAF 45/51 reads (88%) | catalogued as COSV100554977; called by muse, mutect2, varscan2
- GALNT14 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 136/143 reads (95%) | catalogued as COSV100203969, COSV100204550, COSV61110000; called by muse, mutect2, varscan2
- GLI3 | c.4106G>A p.G1369D | Missense Mutation (SNP) | VAF 82/147 reads (56%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV67889561; called by muse, mutect2, varscan2
- GRIPAP1 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64552349; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 151/268 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63100450; called by muse, mutect2, varscan2
- HPCA | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 91/110 reads (83%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV65102999; called by muse, mutect2, varscan2
- HSD11B1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54827884; called by muse, mutect2, varscan2
- IGFALS | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 50/53 reads (94%) | SIFT tolerated (0.88); PolyPhen benign (0.182); catalogued as COSV51906262; called by muse, mutect2, varscan2
- IGLV3-21 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs758035375; called by muse, mutect2, varscan2
- IKZF1 | c.1411T>C p.F471L | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58787010; called by muse, mutect2, varscan2
- ITGAL | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 64/68 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV100776231; called by muse, mutect2, varscan2
- KCNH5 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.142); catalogued as rs763289197, COSV59760952; called by muse, mutect2, varscan2
- KCNQ2 | c.2614A>G p.K872E (on ENST00000359125 / NM_172107.4; = p.K844E on NM_004518.6) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV60546681; called by muse, mutect2, varscan2
- KCTD9 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55340438; called by muse, mutect2, varscan2
- KCTD9 | c.443T>C p.I148T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55340448; called by muse, mutect2, varscan2
- KMT2A | c.2987C>T p.S996F | Missense Mutation (SNP) | VAF 58/59 reads (98%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as COSV63286837; called by muse, mutect2, varscan2
- KRT80 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT tolerated (0.27); PolyPhen benign (0.258); catalogued as rs142483540; called by muse, mutect2, varscan2
- LPAR4 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 140/143 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606517, COSV70912599; called by muse, mutect2, varscan2
- LRP6 | c.3367C>A p.L1123I | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV53788719; called by muse, mutect2, varscan2
- LRRC43 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 161/176 reads (91%) | SIFT tolerated (0.87); PolyPhen benign (0.214); catalogued as rs751280120, COSV60290496; called by muse, mutect2, varscan2
- LRRC49 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.759); catalogued as COSV53011523, COSV53015601; called by muse, mutect2, varscan2
- LTBP2 | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as rs200362889, COSV56209411; called by muse, mutect2, varscan2
- MAGEA12 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 166/167 reads (99%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV63294909; called by muse, mutect2, varscan2
- MC3R | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV54763244; called by muse, mutect2, varscan2
- MMEL1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as rs751529106, COSV56518421; called by muse, mutect2, varscan2
- MMP1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 59/68 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59510648; called by muse, mutect2, varscan2
- MORC1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs752444359, COSV51721820; called by muse, mutect2, varscan2
- MOV10L1 | c.2519C>A p.A840D | Missense Mutation (SNP) | VAF 86/121 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV99433637; called by muse, varscan2
- MTMR10 | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs369814412; called by muse, mutect2, varscan2
- MTMR7 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51666929; called by muse, mutect2, varscan2
- MUC4 | c.13492C>T p.Q4498* (on ENST00000463781 / NM_018406.7; = p.Q262* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as COSV57785085; called by muse, mutect2, varscan2
- NALCN | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99214739; called by muse, mutect2, varscan2
- NDST2 | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT tolerated (0.51); PolyPhen benign (0.054); catalogued as COSV100013895; called by muse, mutect2, varscan2
- NFASC | c.3658G>A p.E1220K (on ENST00000339876 / NM_001378329.1; = p.E1149K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.78); catalogued as COSV58367746; called by muse, mutect2, varscan2
- NLRC3 | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV57091830; called by muse, mutect2, varscan2
- NLRC5 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 33/39 reads (85%) | catalogued as COSV99347135; called by muse, mutect2, varscan2
- NLRP11 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.218); catalogued as COSV64087763; called by muse, mutect2, varscan2
- NRG1 | c.1450C>T p.P484S (on ENST00000405005 / NM_013964.5; = p.P489S on NM_013956.5) | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV55162525; called by muse, mutect2, varscan2
- NXPE4 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV64943902; called by muse, mutect2, varscan2
- OBI1 | c.511T>A p.Y171N | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.676); catalogued as COSV56145948; called by muse, mutect2, varscan2
- OR13C3 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1482973781, COSV66165912, COSV66165960; called by muse, mutect2, varscan2
- OR4K1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs149331048, COSV53458632, COSV53459042; called by muse, mutect2, varscan2
- OR4K13 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.208); catalogued as COSV59859845; called by muse, mutect2, varscan2
- OR52J3 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 52/57 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66747109; called by muse, mutect2, varscan2
- PARP1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.035); catalogued as COSV64687959; called by muse, mutect2
- PARP4 | c.1415T>C p.L472P | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67962468; called by muse, mutect2, varscan2
- PATJ | c.3817G>A p.G1273R | Missense Mutation (SNP) | VAF 75/95 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56250859; called by muse, mutect2, varscan2
- PCDHB5 | c.2362T>G p.F788V | Missense Mutation (SNP) | VAF 100/110 reads (91%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV50654686; called by muse, mutect2, varscan2
- PCNT | c.6886C>T p.P2296S | Missense Mutation (SNP) | VAF 71/120 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.056); catalogued as COSV64029304; called by muse, mutect2, varscan2
- PCSK1 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 135/155 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60735915; called by muse, mutect2, varscan2
- PER2 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 22/23 reads (96%) | catalogued as COSV54524410; called by muse, mutect2, varscan2
- PIDD1 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV61705736; called by muse, mutect2, varscan2
- PIGR | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs149018674; called by muse, varscan2
- PLA2G2A | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs142941380; called by muse, mutect2
- PPP1R3A | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52884472; called by muse, mutect2, varscan2
- PPP4R4 | c.2525C>T p.S842F | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.858); catalogued as COSV58553238; called by muse, mutect2, varscan2
- PRH2 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.995); catalogued as COSV101113304; called by muse, mutect2, varscan2
- PSAPL1 | c.845A>G p.K282R | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59843396; called by muse, mutect2, varscan2
- PSMA4 | c.758A>G p.E253G | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV50384751; called by muse, mutect2, varscan2
- PTPRN2 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV67042507; called by muse, mutect2, varscan2
- RAD54L2 | c.2021C>T p.S674L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs755904833, COSV56578984; called by muse, mutect2, varscan2
- RBM26 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV57395474; called by muse, mutect2, varscan2
- RHEX | c.154G>C p.V52L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV58980738; called by muse, mutect2, varscan2
- RNASEH2A | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 68/103 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55552073; called by muse, mutect2, varscan2
- RNF17 | c.3736C>T p.R1246C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55042018; called by muse, mutect2, varscan2
- ROBO4 | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV60621952; called by muse, mutect2, varscan2
- RTL4 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 119/121 reads (98%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as rs1391421694, COSV61206657; called by muse, mutect2, varscan2
- SERPINA6 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as COSV58585458; called by muse, mutect2, varscan2
- SERPINB4 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as rs750116682, COSV61984264; called by muse, mutect2, varscan2
- SERPIND1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 72/97 reads (74%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1252552768, COSV53139081; called by muse, mutect2, varscan2
- SETD1A | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 87/97 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52688552; called by muse, mutect2, varscan2
- SETD5 | c.2416C>T p.Q806* | Nonsense Mutation (SNP) | VAF 43/86 reads (50%) | catalogued as COSV56712056; called by muse, mutect2, varscan2
- SIGLEC11 | c.1965G>A p.W655* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV68567729; called by muse, mutect2, varscan2
- SLTM | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV51055632, COSV99989122; called by muse, mutect2, varscan2
- SPG11 | c.3796C>T p.L1266F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55996208; called by muse, mutect2, varscan2
- SRCAP | c.8591C>T p.P2864L | Missense Mutation (SNP) | VAF 66/67 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); catalogued as COSV52674191; called by muse, mutect2, varscan2
- SRGAP3 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV64534325; called by muse, mutect2, varscan2
- SYNDIG1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 83/315 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV65235797; called by muse, mutect2, varscan2
- THEG | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV61074050; called by muse, mutect2, varscan2
- TMC5 | c.1213C>T p.Q405* (on ENST00000396229 / NM_001105248.1; = p.Q159* on NM_024780.5) | Nonsense Mutation (SNP) | VAF 109/115 reads (95%) | catalogued as rs745762599, COSV54905156; called by muse, mutect2, varscan2
- TNRC6A | c.4805G>A p.G1602D | Missense Mutation (SNP) | VAF 66/68 reads (97%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.96); catalogued as COSV100169838; called by muse, mutect2, varscan2
- TOX | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 150/161 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309960963, COSV63846955; called by muse, mutect2, varscan2
- TP73 | c.1348C>G p.P450A | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100601183; called by muse, varscan2
- TP73 | c.1349C>G p.P450R | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV100601185; called by muse, varscan2
- TRIM42 | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs555181555, COSV53883796; called by muse, mutect2, varscan2
- TRPC4 | c.63G>T p.R21S | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV100156684, COSV59017220; called by muse, mutect2, varscan2
- TRPC4 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV100156686; called by muse, mutect2, varscan2
- TTN | c.77573C>T p.T25858I (on ENST00000591111; = p.T18434I on NM_003319.4) | Missense Mutation (SNP) | VAF 121/136 reads (89%) | PolyPhen benign (0); catalogued as COSV100610264; called by muse, mutect2, varscan2
- UBQLN3 | c.1350T>G p.D450E | Missense Mutation (SNP) | VAF 61/63 reads (97%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV61164505; called by muse, mutect2, varscan2
- UGT3A2 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as rs769005430, COSV56929023; called by muse, mutect2, varscan2
- UNC13C | c.5680G>A p.D1894N | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52860082; called by muse, mutect2, varscan2
- ZBTB5 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 162/169 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs761993466, COSV57040453; called by muse, mutect2, varscan2
- ZNF174 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 119/272 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV99237376; called by muse, mutect2, varscan2
- ZNF227 | c.1442T>A p.I481N | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.726); catalogued as COSV57312755; called by muse, mutect2, varscan2
- AMY1A | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by mutect2, varscan2
- FRG2B | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FRG2C | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- IGHG1 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- KIR2DL3 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- LRRC37A3 | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.157); called by mutect2, varscan2
- MPND | c.1286_1292del p.Q429Pfs*? | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- RB1 | c.494_497dup p.E166Dfs*6 | Frame Shift Ins (INS) | VAF 15/20 reads (75%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.2002C>T p.H668Y | Missense Mutation (SNP) | VAF 96/99 reads (97%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM3 | c.2941_2965del p.I981* (on ENST00000357533 / NM_001366142.2; = p.I824* on NM_020952.6) | Frame Shift Del (DEL) | VAF 81/113 reads (72%) | called by mutect2, pindel, varscan2
- ABCC11 | c.1551G>A p.E517= | Silent (SNP) | VAF 26/30 reads (87%) | catalogued as COSV62323744; called by muse, mutect2, varscan2
- ACSS2 | c.696G>A p.E232= | Silent (SNP) | VAF 56/83 reads (67%) | catalogued as COSV53625321; called by muse, mutect2, varscan2
- AKNAD1 | c.1851G>A p.V617= | Silent (SNP) | VAF 179/222 reads (81%) | catalogued as COSV62199336; called by muse, mutect2, varscan2
- APCDD1 | c.636C>T p.I212= | Silent (SNP) | VAF 213/380 reads (56%) | catalogued as COSV100789948; called by muse, mutect2, varscan2
- APOB | c.10488C>T p.T3496= | Silent (SNP) | VAF 88/98 reads (90%) | catalogued as rs777594590, COSV51938926; called by muse, mutect2, varscan2
- ARHGAP24 | c.1050G>A p.Q350= (on ENST00000395184 / NM_001025616.3; = p.Q257= on NM_031305.3) | Silent (SNP) | VAF 130/145 reads (90%) | catalogued as rs1195907733, COSV51989938; called by muse, mutect2, varscan2
- ARHGEF25 | c.444G>A p.E148= | Silent (SNP) | VAF 100/107 reads (93%) | catalogued as COSV54087186; called by muse, mutect2, varscan2
- ARID3B | c.504C>T p.V168= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV60557790; called by muse, mutect2, varscan2
- B4GALT7 | c.732C>T p.R244= | Silent (SNP) | VAF 61/65 reads (94%) | catalogued as COSV50353567; called by muse, mutect2, varscan2
- BMP2 | c.222G>A p.V74= | Silent (SNP) | VAF 53/90 reads (59%) | catalogued as COSV66578215; called by muse, mutect2, varscan2
- BRINP1 | c.1536C>T p.L512= | Silent (SNP) | VAF 56/61 reads (92%) | catalogued as rs148767782, COSV56308812; called by muse, mutect2, varscan2
- CCDC158 | c.1788G>A p.E596= | Silent (SNP) | VAF 71/73 reads (97%) | catalogued as COSV66356267; called by muse, mutect2, varscan2
- CDK12 | c.3312T>C p.L1104= | Silent (SNP) | VAF 44/46 reads (96%) | catalogued as COSV71001063; called by muse, mutect2, varscan2
- CEP20 | c.54G>A p.K18= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV99739814; called by muse, mutect2, varscan2
- CETP | c.282G>A p.V94= | Silent (SNP) | VAF 60/64 reads (94%) | catalogued as COSV52362969; called by muse, mutect2, varscan2
- CGNL1 | c.2457G>A p.G819= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV55569540; called by muse, mutect2, varscan2
- CHD2 | c.1827T>C p.I609= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV67710349; called by muse, mutect2, varscan2
- CLCN1 | c.1746C>T p.I582= | Silent (SNP) | VAF 60/127 reads (47%) | catalogued as COSV58370683; called by muse, mutect2, varscan2
- CNGB1 | c.1632G>A p.P544= | Silent (SNP) | VAF 27/31 reads (87%) | catalogued as rs768335062, COSV51901886; called by muse, mutect2, varscan2
- CNTN4 | c.1470A>T p.G490= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV61874488; called by muse, mutect2, varscan2
- CSAG1 | c.171C>T p.F57= | Silent (SNP) | VAF 125/130 reads (96%) | catalogued as rs374336350, COSV63400533; called by muse, mutect2, varscan2
- CYC1 | c.393C>T p.A131= | Silent (SNP) | VAF 316/453 reads (70%) | catalogued as COSV100010368; called by muse, mutect2, varscan2
- DOCK4 | c.615G>A p.Q205= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV70321911; called by muse, mutect2, varscan2
- ERCC5 | c.79C>T p.L27= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs1016196215, COSV99958713; called by muse, mutect2, varscan2
- FAM13A | c.2583G>A p.R861= | Silent (SNP) | VAF 66/81 reads (81%) | catalogued as COSV52004369; called by muse, mutect2, varscan2
- FGF17 | c.264G>A p.V88= | Silent (SNP) | VAF 73/96 reads (76%) | catalogued as rs775839407, COSV63925599; called by muse, mutect2, varscan2
- FRG2B | c.726C>T p.V242= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- FRMD7 | c.2031C>T p.I677= | Silent (SNP) | VAF 109/112 reads (97%) | catalogued as COSV53746702; called by muse, mutect2, varscan2
- GJA10 | c.1488C>T p.F496= | Silent (SNP) | VAF 93/101 reads (92%) | catalogued as COSV65355330; called by muse, mutect2, varscan2
- GLE1 | c.1281C>T p.T427= | Silent (SNP) | VAF 22/27 reads (81%) | catalogued as COSV59408164; called by muse, mutect2, varscan2
- GMIP | c.624G>A p.E208= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV52557008; called by muse, mutect2, varscan2
- HHLA2 | c.1078C>T p.L360= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV63317807; called by muse, mutect2, varscan2
- IGF2R | c.2937C>T p.I979= | Silent (SNP) | VAF 44/51 reads (86%) | catalogued as COSV63629732; called by muse, mutect2, varscan2
- IGFBP1 | c.549C>T p.V183= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs751857594, COSV51874495; called by muse, mutect2, varscan2
- IGLV2-14 | c.354C>T p.L118= | Silent (SNP) | VAF 27/172 reads (16%) | catalogued as rs751163189; called by muse, mutect2, varscan2
- IL37 | c.441G>A p.K147= | Silent (SNP) | VAF 46/50 reads (92%) | catalogued as COSV54491462; called by muse, mutect2, varscan2
- ITGAL | c.1173G>A p.G391= | Silent (SNP) | VAF 63/67 reads (94%) | catalogued as rs754449986, COSV100776232; called by muse, mutect2, varscan2
- KCNH8 | c.2322C>T p.S774= | Silent (SNP) | VAF 62/106 reads (58%) | catalogued as rs999361076, COSV60466326; called by muse, mutect2, varscan2
- LAMA1 | c.2301C>T p.V767= | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as COSV67535668; called by muse, mutect2, varscan2
- LGR5 | c.2418G>A p.L806= | Silent (SNP) | VAF 59/65 reads (91%) | catalogued as COSV57005785; called by muse, mutect2, varscan2
- LRRK1 | c.4446G>A p.P1482= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as rs370936858; called by muse, mutect2, varscan2
- MAP2K7 | c.417C>T p.F139= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as COSV67608533; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3069C>T p.I1023= | Silent (SNP) | VAF 100/106 reads (94%) | catalogued as COSV51601111; called by muse, mutect2, varscan2
- MARVELD2 | c.153C>T p.L51= | Silent (SNP) | VAF 54/67 reads (81%) | catalogued as COSV57781009; called by muse, mutect2, varscan2
- MOV10L1 | c.2520C>T p.A840= | Silent (SNP) | VAF 88/125 reads (70%) | catalogued as rs781714331, COSV53172653; called by muse, varscan2
- MUC4 | c.13725C>T p.G4575= (on ENST00000463781 / NM_018406.7; = p.G339= on NM_004532.6) | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV57785071; called by muse, mutect2, varscan2
- NALCN | c.924C>T p.F308= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV51944037, COSV99214745; called by muse, mutect2, varscan2
- NBEAL2 | c.6171G>A p.E2057= | Silent (SNP) | VAF 42/68 reads (62%) | catalogued as COSV52759084; called by muse, mutect2
- NDST2 | c.2544G>A p.T848= | Silent (SNP) | VAF 24/26 reads (92%) | catalogued as rs780635056, COSV100013896; called by muse, mutect2, varscan2
- NDST3 | c.1509A>G p.G503= | Silent (SNP) | VAF 38/40 reads (95%) | catalogued as COSV56618490; called by muse, mutect2, varscan2
- NLRC5 | c.18C>T p.L6= | Silent (SNP) | VAF 33/39 reads (85%) | catalogued as COSV99347130; called by muse, mutect2, varscan2
- NOD1 | c.1908C>T p.P636= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV56111047; called by muse, mutect2, varscan2
- NSMCE3 | c.697C>T p.L233= | Silent (SNP) | VAF 64/121 reads (53%) | catalogued as COSV99721802; called by muse, mutect2, varscan2
- NSMCE3 | c.696C>T p.Y232= | Silent (SNP) | VAF 64/122 reads (52%) | catalogued as rs373260176, COSV99722865; called by muse, mutect2, varscan2
- NUP210L | c.2733C>T p.N911= | Silent (SNP) | VAF 100/123 reads (81%) | catalogued as rs1242937626, COSV55149628; called by muse, mutect2, varscan2
- OR4K2 | c.798C>T p.L266= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV53849869, COSV53851999; called by muse, mutect2, varscan2
- OR8K3 | c.546C>T p.L182= | Silent (SNP) | VAF 31/38 reads (82%) | catalogued as COSV57131750; called by muse, mutect2, varscan2
- PARP1 | c.3021C>T p.F1007= | Silent (SNP) | VAF 57/69 reads (83%) | catalogued as COSV64690858; called by muse, mutect2, varscan2
- PHOX2B | c.75C>T p.S25= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV56929875; called by muse, mutect2, varscan2
- PPFIA2 | c.261C>T p.S87= | Silent (SNP) | VAF 23/26 reads (88%) | catalogued as COSV61036063; called by muse, mutect2, varscan2
- PRAMEF2 | c.375C>T p.F125= | Silent (SNP) | VAF 336/545 reads (62%) | catalogued as rs1188397790, COSV53576237; called by muse, mutect2, varscan2
- RIN3 | c.1713C>T p.P571= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs746370326, COSV53650146; called by muse, mutect2, varscan2
- RPS6KA6 | c.1362G>A p.V454= | Silent (SNP) | VAF 27/27 reads (100%) | catalogued as COSV53121116; called by muse, mutect2, varscan2
- SHANK3 | c.738C>G p.T246= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV53187371, COSV99436104; called by muse, mutect2, varscan2
- SLTM | c.150C>T p.S50= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99989124, COSV99989387; called by muse, mutect2, varscan2
- STX11 | c.99C>T p.I33= | Silent (SNP) | VAF 20/25 reads (80%) | catalogued as COSV62449456; called by muse, mutect2, varscan2
- TCAF1 | c.321C>T p.G107= | Silent (SNP) | VAF 101/178 reads (57%) | catalogued as rs1274501421, COSV63518279; called by muse, mutect2, varscan2
- TP73 | c.1350C>T p.P450= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as rs771075520, COSV100601169; called by muse, varscan2
- TRAPPC10 | c.1821C>T p.C607= | Silent (SNP) | VAF 21/274 reads (8%) | catalogued as rs1478722487, COSV52378122; called by muse, mutect2
- TSPAN7 | c.510C>T p.I170= | Silent (SNP) | VAF 63/68 reads (93%) | catalogued as COSV54531581; called by muse, mutect2, varscan2
- UBXN11 | c.438C>T p.F146= (on ENST00000374221 / NM_183008.2; = p.F113= on NM_145345.2) | Silent (SNP) | VAF 66/96 reads (69%) | catalogued as COSV59026422; called by muse, mutect2, varscan2
- ZNF174 | c.363G>A p.V121= | Silent (SNP) | VAF 117/273 reads (43%) | catalogued as COSV99237374; called by muse, mutect2, varscan2
- ZNF410 | c.456C>T p.F152= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV57911134; called by muse, mutect2, varscan2
- ZNF547 | c.63C>T p.S21= | Silent (SNP) | VAF 99/171 reads (58%) | catalogued as COSV56580789; called by muse, mutect2, varscan2
- ZNF699 | c.954T>C p.C318= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs1183168676, COSV58025929; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826716 C>T | 3'Flank (SNP) | VAF 157/159 reads (99%) | called by muse, mutect2, varscan2
- BACE2 | c.312+11047C>G | Intron (SNP) | VAF 16/49 reads (33%) | catalogued as COSV57740303; called by muse, mutect2, varscan2
- COL17A1 | c.2228-39T>C | Intron (SNP) | VAF 153/164 reads (93%) | catalogued as COSV100793153; called by muse, mutect2, varscan2
- LINC01600 | n.968C>T | RNA (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- LINC02694 | n.35G>A | RNA (SNP) | VAF 35/84 reads (42%) | catalogued as rs773371984, COSV59558807; called by muse, mutect2, varscan2
- MIR1185-2 | n.51G>A | RNA (SNP) | VAF 3/14 reads (21%) | catalogued as rs1311369211; called by muse, mutect2
- Vault | n.36C>G | RNA (SNP) | VAF 42/44 reads (95%) | called by muse, mutect2, varscan2
